Gene-level copy-number profile of tumor specimen ALCH-B4YS-TTP1-A from ALCHEMIST case ALCH-B4YS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.7 years (26,935 days).
Specimen ALCH-B4YS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e5611fa-99d0-49dd-b922-a770e5dc5188.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4YS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/253b6a03-beba-49a0-a0be-e3a9e36d49f4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,408; copy number 2: 4,504; copy number 3: 12,282; copy number 4: 35,229; copy number 5: 2,518; copy number 6: 2,518; copy number 7: 159; copy number 8: 6; copy number 9: 122; copy number 10: 21; copy number 12: 1; copy number 14: 66; copy number 15: 47; copy number 16: 3.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:85,731,371–85,869,464, 5 genes: AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1.
- chr6:107,192,300–107,192,573, 1 gene (within-gene range 0–2): AL591516.1.
- chr7:6,637,318–6,658,279, 1 gene: ZNF316.
- chr8:22,024,125–22,036,897, 1 gene: NPM2.
- chr22:21,341,595–21,358,067, 2 genes: PPP1R26P5, LINC01651.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 260 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–5,490,220, 114 genes, copy number 9–14 (broad region; genes not listed).
- chr5:6,134,303–8,794,197, 58 genes, copy number 9–15: AC026797.1, HMGB3P3, LINC02145, MED10, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, Metazoa_SRP, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1, RNU1-76P, AC091941.1, AC091912.2, AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3.
- chr5:13,144,000–15,266,541, 24 genes, copy number 9: AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149.
- chr5:16,473,038–17,955,857, 54 genes, copy number 9: RETREG1, AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223.
- chr5:135,802,985–135,803,075, 1 gene, copy number 15: MIR5692C1.
- chr7:7,066,964–7,067,045, 1 gene, copy number 12: MIR3683.
- chr16:10,718,633–10,721,464, 3 genes, copy number 16: MTCYBP33, MTND6P33, MTND5P33.
- chr19:1,103,926–1,106,791, 1 gene, copy number 9: GPX4.
- chr19:1,248,553–1,279,244, 4 genes, copy number 9: MIDN, CIRBP, CIRBP-AS1, FAM174C.

Autosomal genes at a single copy (total copy number 1): 192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
